Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6AN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6AN-01A (Primary Tumor).

[page 1 of 3]
Report for [REDACTED]

TEST: Surgical Pathology

Collected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
Surgical Pathology	SURGICAL P		
SURGICAL PATHOLOGY REPORT			

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med. Rec. #: [REDACTED]

Billing Type: [REDACTED]

Location:

DOB: (Age: [REDACTED])

Service: [REDACTED]

Gender: M

Billing: [REDACTED]

Taken: [REDACTED] Received: [REDACTED]

Physician(s): [REDACTED]

CCCF ICD-O-3
Adenocarcinoma, Acinar 8140/3
Path
Adenocarcinoma NOS 8140/3
Site: Prostate C61.9

Reported: [REDACTED]

Specimen(s) Received

A: Right iliac and obturator lymph nodes

B: Prostate

Pathologic Diagnosis

A. Right iliac and obturator lymph nodes:

- One benign lymph node (0/1).

B. Prostate, prostatectomy:

- Prostatic adenocarcinoma, Gleason grade 4 + 3 (sum = 7).

- There is extensive involvement of gland bilaterally with approximately 20% of the gland showing involvement by tumor.

- Focal extraprostatic extension is identified at the right apex and right anterior prostate. This consists of two small foci of tumor within fat, each measuring approximately 1-2 mm.

- Tumor is identified at the surgical margin at the right anterior prostate (1 mm) and posteriorly on both the right and left sides as a few foci all < 1mm.

- Benign seminal vesicles.

SYNOPTIC REPORT: PROSTATE GLAND, RADICAL PROSTATECTOMY

Procedure: Radical prostatectomy

Prostate Size:

Weight: 29 g

Size: 4.0 x 3.8 x 3.0 cm

Lymph Node Sampling: Pelvic lymph node dissection

Histologic Type: Adenocarcinoma

Histologic Grade/Gleason Pattern:

Primary Pattern: 4

Secondary Pattern: 3

Tertiary Pattern: Not applicable

Total Gleason Score: 7

Tumor Quantitation:

Proportion of prostate involved by tumor: 20%

Extraprostatic Extension: Present, focal, right apex

Seminal Vesicle Invasion: Not identified

Margins: Involved by invasive carcinoma, focal anterior and posterior

[REDACTED]

[page 2 of 3]
Treatment Effect on Carcinoma: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

PATHOLOGIC STAGE: pT3a N0 MX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Primary Pathologist: [REDACTED]
[REDACTED] Electronically Signed Out by: [REDACTED]

Clinical History

Prostate cancer.

Intraoperative Consultation

A. Right iliac and obturator lymph nodes: One benign lymph node (microscopic evaluation).
[REDACTED]

Gross Description

A. Received fresh for frozen section labeled "right iliac and obturator lymph nodes" is a single lymph node measuring 3.2 cm in greatest dimension. The specimen is inked yellow and entirely submitted in cassette A1FS.

B. Received in formalin labeled "prostate" is a 29 gram, 4.0 cm from left to right, 3.8 cm from anterior to posterior, 3.0 cm from apex to bladder neck margin prostatectomy specimen with attached right seminal vesicle (3.0 x 1.3 x 0.5 cm), right vas deferens (2.8 x 0.7 x 0.4 cm), left seminal vesicle (3.0 x 1.5 x 1.0 cm), left vas deferens (3.0 x 0.8 x 0.5 cm). The prostate is inked as follows: the right prostate is inked blue, the left prostate is inked black and bladder neck margin is inked yellow. The prostate is serially sectioned from apex to bladder neck margin to reveal a 2.0 cm in greatest dimension firm, white-tan lesion located in the right posterior and anterior prostate. The lesion does not grossly cross the midline into the left posterior prostate. The lesion grossly abuts the blue-inked margin. There are other discrete nodules or masses grossly identified and the remaining prostate parenchyma is pink-tan. Ninety percent (90%) of the specimen is submitted in cassettes B1-B20.

Sections are submitted as follows:

B1-B2 - right apex, perpendicularly cut;

B3-B4 - left apex, perpendicularly cut;

B5-B6 - right bladder neck margin, perpendicularly cut;

B7-B8 - left bladder neck margin, perpendicularly cut;

B9 - right seminal vesicle insertion point and cross section through right seminal vesicle and vas deferens;

B10 - left seminal vesicle insertion point and cross section through right seminal vesicle and vas deferens;

B11 - right anterior prostate;

B12-B15 - right posterior prostate, from apex to bladder neck margin;

B16 - left anterior prostate;

[REDACTED]

[page 3 of 3]
B17-B20 - left posterior prostate, from apex to bladder neck margin.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Interpretation performed at [REDACTED]
If immunohistochemistry or in situ hybridization was used the following applies: This test was developed and its performance characteristic determined by [REDACTED] It has not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. All special stains used have adequate controls.

CLIA #	W 5/5/13	Yes	No
HPA Discrepancy			✓
Reviewed (Initials)	Date Reviewed: 4/30/13		

Source: NCI Genomic Data Commons file 1dcb8695-49bc-412d-b39c-3807236cbc7e (TCGA-HC-A6AN.D5C8CC7E-BADE-457C-AC31-CC138C8C794C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).